Somatic mutation profile of tumor specimen 0DE65R from CCDI case PBBPKC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.7 years (1,708 days).
Specimen 0DE65R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6d0ef43-ff85-4655-b4e1-d248fdf3f15a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE3GT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f2eb35c-bd4e-4908-9e21-3b8c942fb5a9

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USP17L17 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 58/1548 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.042); catalogued as rs1348310188; called by muse, mutect2
- WASHC2C | c.2855C>T p.T952I | Missense Mutation (SNP) | VAF 156/738 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- LILRB5 | c.-4C>T | 5'UTR (SNP) | VAF 25/420 reads (6%) | catalogued as rs375650048; called by muse, mutect2
- PRSS57 | c.*59C>A | 3'UTR (SNP) | VAF 4/40 reads (10%) | called by muse, varscan2
- ZNF107 | c.*76C>G | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, varscan2
